Somatic mutation profile of tumor specimen C3L-06459-01 (aliquot CPT0483560006) from CPTAC case C3L-06459, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 73.0 years (26,661 days).
Specimen C3L-06459-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ec918aa1-5dc1-423a-8355-c00a22e4bb65.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06459-31 (Blood Derived Normal), aliquot CPT0483710005; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c5234085-cd69-4561-826d-45c1e0685c76

The open-access MAF lists 103 somatic variants for this specimen: 70 protein-altering or splice-affecting, 30 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 58, Silent 30, Nonsense Mutation 8, Splice Region 2, Intron 2, RNA 1, Frame Shift Del 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IGHMBP2 | c.958C>T p.R320* | Nonsense Mutation (SNP) | VAF 39/311 reads (13%) | catalogued as rs773690764, CM035785; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- PDGFRA | c.451C>T p.R151C | Missense Mutation (SNP) | VAF 49/283 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); catalogued as rs1449637193, COSV57268466; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- SMARCB1 | c.992G>A p.R331H (on ENST00000263121; = p.R377H on NM_003073.5) | Missense Mutation (SNP) | VAF 153/332 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs387906812, CM122478, COSV51954090, COSV51954233, COSV51954740; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.830G>A p.C277Y | Missense Mutation (SNP) | VAF 108/227 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs763098116, CM078491, COSV52693726, COSV52826087, COSV53107923; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ADAMTSL1 | c.3503G>A p.R1168H | Missense Mutation (SNP) | VAF 63/384 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); catalogued as rs758209178, COSV65893747; called by muse, mutect2, varscan2
- CACNA1H | c.3744C>T p.D1248= | Splice Region (SNP) | VAF 94/255 reads (37%) | catalogued as rs747200195, COSV61999936; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CARMIL3 | c.2657G>A p.R886Q | Missense Mutation (SNP) | VAF 79/472 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.11); catalogued as rs763222738, COSV57725186; called by muse, mutect2, varscan2
- CLASRP | c.325C>T p.R109W | Missense Mutation (SNP) | VAF 69/235 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); catalogued as rs925218809; called by muse, mutect2, varscan2
- CST2 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 38/452 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.36); catalogued as rs541427772, COSV100491066, COSV100491333; called by muse, mutect2
- CTNND2 | c.1091G>A p.R364H | Missense Mutation (SNP) | VAF 152/329 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs905114117, COSV58917426; called by muse, mutect2, varscan2
- DISP3 | c.2928A>T p.K976N | Missense Mutation (SNP) | VAF 24/203 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.051); catalogued as COSV53824837, COSV99608510; called by muse, mutect2, varscan2
- DLG4 | c.1837G>A p.V613I (on ENST00000399506 / NM_001321075.3; = p.V656I on NM_001365.4) | Missense Mutation (SNP) | VAF 107/211 reads (51%) | SIFT tolerated (0.38); PolyPhen benign (0.276); catalogued as COSV57239069; called by muse, mutect2, varscan2
- DMRT2 | c.565C>T p.R189C | Missense Mutation (SNP) | VAF 92/222 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs201585505, COSV52402687; called by muse, varscan2
- EP400 | c.74G>T p.G25V | Missense Mutation (SNP) | VAF 63/265 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.26); catalogued as rs1179362320; called by muse, mutect2, varscan2
- FAM83H | c.910G>A p.G304R | Missense Mutation (SNP) | VAF 105/772 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs1464113197, COSV66354300; called by muse, mutect2, varscan2
- FAT4 | c.13832C>A p.P4611H | Missense Mutation (SNP) | VAF 52/347 reads (15%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.998); catalogued as COSV100627407; called by muse, mutect2, varscan2
- FSIP2 | c.15428A>C p.K5143T | Missense Mutation (SNP) | VAF 80/197 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV100555467; called by muse, mutect2, varscan2
- GFI1B | c.569G>A p.R190Q | Missense Mutation (SNP) | VAF 110/308 reads (36%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); catalogued as rs192854759, COSV100253976; called by mutect2, varscan2
- HERC5 | c.2677G>A p.D893N | Missense Mutation (SNP) | VAF 35/263 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.022); catalogued as rs551404590; called by muse, mutect2, varscan2
- IQGAP2 | c.323G>A p.R108Q | Missense Mutation (SNP) | VAF 38/195 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs764865648, COSV57171272; called by muse, mutect2, varscan2
- KCNT2 | c.2699C>G p.S900* | Nonsense Mutation (SNP) | VAF 51/188 reads (27%) | catalogued as COSV54105778; called by muse, mutect2, varscan2
- KMT2B | c.2884C>T p.R962C | Missense Mutation (SNP) | VAF 157/348 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1385766471, COSV55859337; called by muse, mutect2, varscan2
- LRP1B | c.6458G>A p.G2153D | Missense Mutation (SNP) | VAF 68/197 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.44); catalogued as rs202108597; called by muse, mutect2, varscan2
- MAST3 | c.3757C>T p.R1253W | Missense Mutation (SNP) | VAF 151/459 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.824); catalogued as rs1208178913; called by muse, mutect2, varscan2
- MATK | c.460G>A p.G154S (on ENST00000310132 / NM_139355.3; = p.G155S on NM_002378.4) | Missense Mutation (SNP) | VAF 65/378 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200600761; called by muse, mutect2, varscan2
- MRNIP | c.479C>T p.P160L | Missense Mutation (SNP) | VAF 54/288 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as rs185437892; called by muse, mutect2, varscan2
- MYT1 | c.1682G>A p.R561Q | Missense Mutation (SNP) | VAF 69/883 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs759933398, COSV60507396; called by muse, mutect2
- NAV1 | c.1081C>A p.R361S | Missense Mutation (SNP) | VAF 91/340 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.035); catalogued as COSV55218445; called by muse, mutect2, varscan2
- NBPF14 | c.2586G>C p.R862S | Missense Mutation (SNP) | VAF 12/258 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as rs1229205373; called by muse, mutect2
- NFATC4 | c.991C>T p.R331W | Missense Mutation (SNP) | VAF 102/453 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99144493; called by muse, mutect2, varscan2
- NKX2-4 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 71/621 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1568605814; called by muse, mutect2, varscan2
- NUFIP1 | c.1066G>A p.E356K | Missense Mutation (SNP) | VAF 50/343 reads (15%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.912); catalogued as COSV64791938; called by muse, mutect2, varscan2
- NYAP2 | c.730G>A p.V244M | Missense Mutation (SNP) | VAF 62/398 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1311059994, COSV56017053; called by muse, mutect2, varscan2
- OPLAH | c.3136G>A p.D1046N | Missense Mutation (SNP) | VAF 41/351 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1554758013; called by muse, mutect2, varscan2
- PCDHA2 | c.1129C>T p.R377C | Missense Mutation (SNP) | VAF 78/338 reads (23%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.276); catalogued as rs781879420, COSV65369803; called by muse, mutect2, varscan2
- PDZRN4 | c.1438G>A p.V480M (on ENST00000402685 / NM_001164595.2; = p.V222M on NM_013377.4) | Missense Mutation (SNP) | VAF 71/189 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.739); catalogued as rs751304304, COSV54212937; called by muse, mutect2, varscan2
- PLEKHN1 | c.1388G>A p.G463E (on ENST00000379409; = p.G411E on NM_032129.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 127/343 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as rs1245884274; called by muse, mutect2, varscan2
- PTPRT | c.4109G>A p.R1370K | Missense Mutation (SNP) | VAF 50/425 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.18); catalogued as rs758242008; called by muse, mutect2, varscan2
- RBP3 | c.799C>T p.R267W | Missense Mutation (SNP) | VAF 143/424 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs782577134; called by muse, mutect2, varscan2
- RIPOR3 | c.2513C>T p.A838V | Missense Mutation (SNP) | VAF 160/757 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.023); catalogued as rs201227209; called by muse, varscan2
- RNF145 | c.119G>A p.R40K (on ENST00000424310 / NM_001199383.2; = p.R68K on NM_144726.2) | Missense Mutation (SNP) | VAF 36/279 reads (13%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.987); catalogued as COSV50866406; called by muse, mutect2, varscan2
- SIGLEC1 | c.3845C>T p.A1282V | Missense Mutation (SNP) | VAF 197/573 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.223); catalogued as rs569142336; called by muse, mutect2, varscan2
- UNC13C | c.6448G>A p.G2150R | Missense Mutation (SNP) | VAF 41/339 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs753460509, COSV52876360; called by muse, mutect2, varscan2
- WT1 | c.919G>T p.E307* | Nonsense Mutation (SNP) | VAF 42/422 reads (10%) | catalogued as COSV60080075; called by muse, mutect2
- ZFHX4 | c.5119G>A p.A1707T | Missense Mutation (SNP) | VAF 88/454 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs764848741, COSV51500075; called by muse, mutect2, varscan2
- ZNF536 | c.1964G>A p.R655Q | Missense Mutation (SNP) | VAF 73/1952 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.383); catalogued as rs1449896480; called by muse, mutect2
- ADGB | c.246del p.F82Lfs*14 | Frame Shift Del (DEL) | VAF 11/79 reads (14%) | called by mutect2, pindel, varscan2
- ATP6V1A | c.338C>A p.T113N | Missense Mutation (SNP) | VAF 53/259 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- AZI2 | c.988G>T p.G330C | Missense Mutation (SNP) | VAF 58/297 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CCNE1 | c.770C>T p.A257V | Missense Mutation (SNP) | VAF 48/1770 reads (3%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.982); called by muse, mutect2
- CDH22 | c.1375C>G p.R459G | Missense Mutation (SNP) | VAF 52/782 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CLASP1 | c.1444C>T p.R482* | Nonsense Mutation (SNP) | VAF 38/254 reads (15%) | called by muse, mutect2, varscan2
- DGKZ | c.1534C>T p.R512* (on ENST00000454345 / NM_001105540.2; = p.R324* on NM_003646.4) | Nonsense Mutation (SNP) | VAF 55/295 reads (19%) | called by muse, mutect2, varscan2
- DNAJC14 | c.1519C>T p.R507* | Nonsense Mutation (SNP) | VAF 27/157 reads (17%) | called by muse, mutect2, varscan2
- DPYD | c.1908T>C p.I636= | Splice Region (SNP) | VAF 52/186 reads (28%) | called by muse, mutect2, varscan2
- EIF2B1 | c.706G>A p.V236I | Missense Mutation (SNP) | VAF 33/176 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.27); called by muse, mutect2, varscan2
- ELFN1 | c.839C>T p.P280L | Missense Mutation (SNP) | VAF 103/511 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ITGB2 | c.1277G>A p.G426D (on ENST00000302347; = p.G402D on NM_000211.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/225 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- KDM5C | c.1714_1731del p.N572_M577del | In Frame Del (DEL) | VAF 88/150 reads (59%) | called by mutect2, varscan2
- LSM14B | c.754G>C p.D252H | Missense Mutation (SNP) | VAF 107/638 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- MSANTD4 | c.26A>G p.K9R | Missense Mutation (SNP) | VAF 22/289 reads (8%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.802); called by muse, mutect2
- NEXMIF | c.108G>T p.K36N | Missense Mutation (SNP) | VAF 44/154 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- NUDT6 | c.20G>A p.W7* | Nonsense Mutation (SNP) | VAF 76/221 reads (34%) | called by muse, mutect2, varscan2
- PSG11 | c.949A>T p.T317S | Missense Mutation (SNP) | VAF 75/159 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- PSMD1 | c.2203G>A p.G735S | Missense Mutation (SNP) | VAF 31/215 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RTL4 | c.796C>A p.L266I | Missense Mutation (SNP) | VAF 12/244 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.562); called by muse, mutect2
- SEMA5A | c.880A>G p.T294A | Missense Mutation (SNP) | VAF 61/159 reads (38%) | SIFT tolerated (0.65); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- TMC3 | c.1809C>A p.C603* | Nonsense Mutation (SNP) | VAF 85/252 reads (34%) | called by muse, mutect2, varscan2
- TRIM72 | c.253C>T p.H85Y | Missense Mutation (SNP) | VAF 81/411 reads (20%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.741); called by muse, mutect2, varscan2
- WNK2 | c.3434C>T p.S1145F | Missense Mutation (SNP) | VAF 105/271 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- AL592490.1 | c.1356G>A p.A452= | Silent (SNP) | VAF 55/408 reads (13%) | catalogued as rs777755843, COSV69426569; called by muse, mutect2
- ASXL3 | c.2343G>A p.P781= | Silent (SNP) | VAF 154/292 reads (53%) | catalogued as rs199958610, COSV52462323; called by muse, mutect2, varscan2
- AURKAIP1 | c.558C>T p.P186= | Silent (SNP) | VAF 48/205 reads (23%) | catalogued as rs768888780; called by muse, mutect2, varscan2
- CSMD1 | c.7584T>A p.L2528= (on ENST00000520002; = p.L2527= on NM_033225.6) | Silent (SNP) | VAF 49/223 reads (22%) | called by muse, mutect2, varscan2
- DYRK2 | c.1620A>G p.P540= (on ENST00000344096 / NM_006482.3; = p.P467= on NM_003583.4) | Silent (SNP) | VAF 55/734 reads (7%) | called by muse, mutect2
- FRYL | c.2286G>A p.S762= | Silent (SNP) | VAF 21/165 reads (13%) | catalogued as rs769733331; called by muse, mutect2, varscan2
- GDA | c.318C>T p.Y106= | Silent (SNP) | VAF 53/269 reads (20%) | catalogued as rs1243368760; called by muse, mutect2, varscan2
- HMGXB3 | c.2052C>A p.V684= (on ENST00000613459; = p.V438= on NM_014983.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 107/268 reads (40%) | called by muse, mutect2, varscan2
- HOXD13 | c.144G>C p.V48= | Silent (SNP) | VAF 53/350 reads (15%) | called by muse, mutect2, varscan2
- INF2 | c.345C>T p.I115= | Silent (SNP) | VAF 59/272 reads (22%) | catalogued as rs1436446364; called by muse, mutect2, varscan2
- KPNB1 | c.1410G>A p.V470= | Silent (SNP) | VAF 66/173 reads (38%) | called by muse, mutect2, varscan2
- MATN4 | c.1623G>A p.A541= (on ENST00000372754; = p.A500= on NM_003833.4) | Silent (SNP) | VAF 54/691 reads (8%) | catalogued as COSV61351932; called by muse, mutect2
- MXRA5 | c.63G>A p.P21= | Silent (SNP) | VAF 148/227 reads (65%) | catalogued as COSV54226209; called by muse, mutect2, varscan2
- NFKBIZ | c.1161G>A p.G387= | Silent (SNP) | VAF 64/358 reads (18%) | called by muse, mutect2, varscan2
- NSMF | c.96C>T p.Y32= | Silent (SNP) | VAF 96/341 reads (28%) | called by muse, mutect2, varscan2
- NUP214 | c.3195C>T p.A1065= | Silent (SNP) | VAF 51/245 reads (21%) | called by muse, mutect2, varscan2
- OBSCN | c.7086C>T p.D2362= | Silent (SNP) | VAF 38/348 reads (11%) | catalogued as rs781470946, COSV52758186; called by muse, mutect2, varscan2
- OTOGL | c.2985C>T p.N995= (on ENST00000547103; = p.N986= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 40/155 reads (26%) | catalogued as rs374656183; called by muse, mutect2, varscan2
- PARD3 | c.609G>A p.P203= | Silent (SNP) | VAF 47/171 reads (27%) | catalogued as rs761313152; called by muse, mutect2, varscan2
- PHF14 | c.105T>C p.D35= | Silent (SNP) | VAF 59/174 reads (34%) | called by muse, mutect2, varscan2
- PLEC | c.13704C>T p.Y4568= (on ENST00000322810 / NM_201380.4; = p.Y4458= on NM_000445.5) | Silent (SNP) | VAF 95/595 reads (16%) | catalogued as COSV59636487; called by muse, mutect2, varscan2
- SALL4 | c.2253C>T p.N751= | Silent (SNP) | VAF 60/557 reads (11%) | catalogued as rs745976757; called by muse, mutect2, varscan2
- SELE | c.948G>A p.R316= | Silent (SNP) | VAF 93/337 reads (28%) | called by muse, mutect2, varscan2
- SF3A1 | c.1854G>A p.P618= | Silent (SNP) | VAF 62/287 reads (22%) | catalogued as rs774519141, COSV53167850; called by muse, mutect2, varscan2
- SNX17 | c.535T>C p.L179= | Silent (SNP) | VAF 81/205 reads (40%) | called by muse, mutect2, varscan2
- SOX1 | c.837C>T p.G279= | Silent (SNP) | VAF 13/109 reads (12%) | called by muse, mutect2, varscan2
- TNFRSF1A | c.1278C>T p.R426= | Silent (SNP) | VAF 71/349 reads (20%) | catalogued as COSV50607007; called by muse, mutect2, varscan2
- TSPYL6 | c.231G>A p.A77= | Silent (SNP) | VAF 58/365 reads (16%) | catalogued as rs776739294; called by muse, mutect2, varscan2
- TTLL1 | c.846C>T p.F282= | Silent (SNP) | VAF 94/199 reads (47%) | catalogued as rs768299826, COSV99840272; called by muse, mutect2, varscan2
- WIZ | c.4947C>T p.A1649= (on ENST00000673675 / NM_001371589.1; = p.A554= on NM_021241.3) | Silent (SNP) | VAF 136/407 reads (33%) | called by muse, mutect2, varscan2
- NOTCH2 | c.751+254C>G | Intron (SNP) | VAF 25/227 reads (11%) | called by muse, mutect2, varscan2
- SLC66A1L | n.469G>A | RNA (SNP) | VAF 32/203 reads (16%) | catalogued as rs1368197468; called by muse, mutect2, varscan2
- TTN | c.10303+2497C>T | Intron (SNP) | VAF 94/215 reads (44%) | catalogued as rs1254851346, COSV100619023; called by muse, mutect2, varscan2
